Gene-level copy-number profile of tumor specimen C3N-02285-03 from CPTAC case C3N-02285, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 72.8 years (26,573 days).
Specimen C3N-02285-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 001d5f4b-8c4e-4243-b02f-d007c20d8405.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02285-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/9831cc89-d80b-4e91-afde-2df886279614

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 15,829; copy number 2: 38,951; copy number 3: 2,623; copy number 4: 4; copy number 5: 140; copy number 6: 678; copy number 7: 1; copy number 8: 22; copy number 10: 35; copy number 13: 2; copy number 14: 4; copy number 19: 2; copy number 21: 2; copy number 22: 16; copy number 35: 1; copy number 51: 1; copy number 54: 8; copy number 82: 7.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:119,759,922–119,984,899, 1 gene: PTPN4.
- chr2:176,338,637–176,339,077, 1 gene: PPIAP67.
- chr6:136,550,661–136,552,554, 1 gene (within-gene range 0–2): AL024508.1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,892,188–22,214,672, 11 genes (within-gene range 0–1): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:42,183,659–60,964,196, 36 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1, FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr12:43,793,723–43,806,328, 1 gene: TWF1.
- chr15:91,853,708–92,809,884, 24 genes (within-gene range 0–2): SLCO3A1, AC116903.2, AC116903.1, DUXAP6, NPM1P5, ST8SIA2, AC090985.1, ENO1P2, AC090985.2, C15orf32, LINC00930, AC091544.2, AC091544.4, AC091544.5, FAM174B, AC091544.3, AC091544.7, AC091544.6, HMGN1P38, H2AZ2P1, AC091544.1, AC106028.1, AC106028.3, ASB9P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 919 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 679 genes, copy number 6–7 (broad region; genes not listed).
- chr7:53,862,233–57,837,046, 144 genes, copy number 5–82 (broad region; genes not listed).
- chr7:107,563,484–108,995,029, 29 genes, copy number 5–8 (within-gene range 2–8): DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr8:37,626,015–39,580,134, 61 genes, copy number 8–35 (broad region; genes not listed).
- chr9:61,190,003–61,453,030, 6 genes, copy number 5–14: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, CNTNAP3C, RN7SL462P.

Autosomal genes at a single copy (total copy number 1): 15,829. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
